Gene-level copy-number profile of tumor specimen MP2PRT-PATILY-TTP1-A from MP2PRT case MP2PRT-PATILY, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 6.1 years (2,246 days).
Specimen MP2PRT-PATILY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 18a064b4-eed1-40ab-86ff-bbe443a2105f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATILY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/553d3dae-a0e2-42c7-9bec-563c2a5327e7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,991; copy number 2: 46,161; copy number 3: 4,238; copy number 4: 4; copy number 5: 2,474; copy number 6: 46.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,520 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–144,419,192, 41 genes, copy number 6: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2.
- chr1:144,523,860–196,747,504, 1,345 genes, copy number 5–6 (broad region; genes not listed).
- chr1:196,819,731–248,937,043, 1,134 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
